Somatic mutation profile of tumor specimen TCGA-ED-A7XO-01A (aliquot TCGA-ED-A7XO-01A-11D-A34Z-10) from TCGA case TCGA-ED-A7XO, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 29.6 years (10,828 days).
Specimen TCGA-ED-A7XO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8bb555b9-2313-401c-a91c-6a2e9d68b6d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ED-A7XO-10A (Blood Derived Normal), aliquot TCGA-ED-A7XO-10A-01D-A34Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ccb49b6-c661-4c6b-94fc-ea55dad35d04

The open-access MAF lists 63 somatic variants for this specimen: 50 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 12, Nonsense Mutation 2, 5'UTR 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.770T>C p.L257P | Missense Mutation (SNP) | VAF 16/62 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934577, CD941800, CM1411657, CM941332, COSV52682484, COSV52703253, COSV52757928; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABR | c.2572G>A p.D858N (on ENST00000302538 / NM_021962.5; = p.D821N on NM_001092.5) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.102); catalogued as rs751168415, COSV52145898; called by muse, mutect2, varscan2
- ADGRE3 | c.1411G>A p.G471S | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs553930762, COSV53729841; called by muse, mutect2, varscan2
- ADGRG4 | c.7100T>C p.L2367S | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV54956673; called by muse, mutect2, varscan2
- AHSA1 | c.564T>G p.A188= | Splice Region (SNP) | VAF 7/34 reads (21%) | catalogued as COSV53631966; called by muse, mutect2, varscan2
- ALDH1A2 | c.1207G>T p.V403L | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV51081908; called by muse, mutect2, varscan2
- ANGPT1 | c.522G>C p.E174D | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV52440779; called by muse, mutect2, varscan2
- AP2A2 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59960471; called by muse, mutect2, varscan2
- ARMH4 | c.2108A>G p.K703R | Missense Mutation (SNP) | VAF 82/539 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV50764786; called by muse, mutect2, varscan2
- ASPSCR1 | c.136A>G p.N46D | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.894); catalogued as COSV100144875; called by muse, mutect2
- CIP2A | c.1609C>G p.P537A | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV55417210, COSV55418843; called by muse, mutect2, varscan2
- CLIP1 | c.808G>A p.G270S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56802179; called by muse, mutect2, varscan2
- CTNNBL1 | c.1392+1G>A p.X464_splice | Splice Site (SNP) | VAF 16/83 reads (19%) | catalogued as rs766206506, COSV63744937; called by muse, mutect2, varscan2
- CUX2 | c.215A>T p.Q72L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55632952; called by muse, mutect2, varscan2
- CWC27 | c.269G>T p.R90L | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66885913, COSV66885937; called by muse, mutect2, varscan2
- DDX5 | c.1126A>G p.S376G | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as COSV56749142; called by muse, mutect2, varscan2
- DDX58 | c.763A>G p.M255V | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs921634647, COSV65883286; called by muse, mutect2, varscan2
- DOCK8 | c.1909G>T p.A637S | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as rs771347031, COSV66620313, COSV66621457; called by muse, mutect2, varscan2
- DYNC2H1 | c.2367G>C p.R789S | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV62094700; called by muse, mutect2, varscan2
- ENTPD6 | c.1078G>T p.V360L | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.147); catalogued as COSV61751541; called by muse, mutect2, varscan2
- EWSR1 | c.1694G>T p.R565I | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as COSV58421231, COSV58423772; called by muse, mutect2, varscan2
- FAF1 | c.111A>T p.L37F | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65638693; called by muse, mutect2, varscan2
- FLG | c.5368C>A p.Q1790K | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.761); catalogued as CM108253, COSV64242229; called by muse, mutect2, varscan2
- HEATR5B | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.271); catalogued as COSV51853007; called by muse, mutect2, varscan2
- HECW2 | c.4440G>T p.W1480C | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53660379; called by muse, mutect2, varscan2
- HMCN1 | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as rs1187160192, COSV54902177; called by muse, mutect2, varscan2
- HTR3C | c.180C>A p.Y60* | Nonsense Mutation (SNP) | VAF 15/75 reads (20%) | catalogued as COSV59175441; called by muse, mutect2, varscan2
- KCNH5 | c.406C>A p.Q136K | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV59761006; called by muse, mutect2, varscan2
- KIAA1549 | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV54314798; called by muse, mutect2, varscan2
- KIF14 | c.2563T>G p.F855V | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV66261853; called by muse, mutect2, varscan2
- KLHL35 | c.1510T>A p.Y504N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66219351; called by muse, mutect2, varscan2
- LCA5 | c.1409A>G p.K470R | Missense Mutation (SNP) | VAF 48/221 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV63971448; called by muse, mutect2, varscan2
- MYB | c.847C>A p.H283N | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); catalogued as COSV57198347; called by muse, mutect2, varscan2
- NAGK | c.823A>T p.S275C | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54903652; called by muse, mutect2, varscan2
- OR2A5 | c.872G>T p.S291I | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV101278846, COSV68738765; called by muse, mutect2, varscan2
- PDE3A | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as COSV62973458; called by muse, mutect2, varscan2
- PDE4B | c.313C>G p.R105G | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.388); catalogued as COSV58477689; called by muse, mutect2, varscan2
- PEAK1 | c.4078A>T p.I1360F | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56935892; called by muse, mutect2, varscan2
- PLAG1 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.848); catalogued as rs144724863; called by muse, mutect2
- PLXNB1 | c.5800G>T p.D1934Y | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56489907; called by muse, mutect2
- RAI2 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs748047813, COSV58964423; called by muse, mutect2, varscan2
- RSL24D1 | c.350A>G p.E117G | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV53065597; called by muse, mutect2, varscan2
- SNAP91 | c.2446G>T p.G816* | Nonsense Mutation (SNP) | VAF 26/115 reads (23%) | catalogued as COSV52122862; called by muse, mutect2, varscan2
- SPTBN2 | c.4756G>T p.D1586Y | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV59452448; called by muse, mutect2, varscan2
- TAS1R3 | c.149G>A p.G50D | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV59563519; called by muse, mutect2, varscan2
- TKTL2 | c.1148G>T p.R383L | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV54919000; called by muse, mutect2, varscan2
- VCAN | c.7817A>G p.H2606R | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV54105627; called by muse, mutect2, varscan2
- WDR17 | c.403T>C p.C135R | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54574545; called by muse, mutect2, varscan2
- WDR19 | c.2617G>T p.A873S | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56465477; called by muse, mutect2
- ZIC4 | c.494G>C p.G165A | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV67171930; called by muse, mutect2, varscan2
- CDH23 | c.705C>A p.I235= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as COSV54935313; called by muse, mutect2, varscan2
- CERS5 | c.135G>A p.R45= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100451994; called by muse, mutect2
- CRACD | c.1188G>A p.A396= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs1038038281, COSV51721578; called by muse, mutect2, varscan2
- GPR12 | c.756C>A p.T252= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV101197978; called by muse, mutect2
- IGFN1 | c.3714A>T p.A1238= (on ENST00000295591 / NM_001367841.1; = p.A3695= on NM_001164586.2) | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV55173160; called by muse, mutect2, varscan2
- OR10H5 | c.726T>C p.C242= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as rs1335779931, COSV58278209; called by muse, mutect2, varscan2
- PREX2 | c.135G>T p.L45= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as COSV55771593; called by muse, mutect2, varscan2
- PTCHD1 | c.819C>A p.V273= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs769884877, COSV65060213; called by muse, mutect2, varscan2
- S1PR3 | c.18G>A p.P6= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs1410965214, COSV63980637; called by muse, mutect2, varscan2
- SLC7A9 | c.903T>A p.A301= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs774424761, COSV50085733; called by muse, mutect2
- SLCO4C1 | c.1386A>G p.G462= | Silent (SNP) | VAF 71/334 reads (21%) | catalogued as COSV60515987; called by muse, mutect2, varscan2
- UBR4 | c.15054G>T p.L5018= | Silent (SNP) | VAF 23/86 reads (27%) | catalogued as COSV64390119, COSV64390179; called by muse, mutect2, varscan2
- CENPO | c.-101C>T | 5'UTR (SNP) | VAF 23/87 reads (26%) | catalogued as COSV53230590; called by muse, mutect2, varscan2
